TARGET case TARGET-30-PASVRU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0500d47a-3db5-5fcc-a92a-08955927b17d

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 1 years; Vital status: Dead; Days to death: 440 days (1.2 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 1.7 years (631 days); Year of diagnosis: 2009; Days to last follow up: 440 days (1.2 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 80.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0532.

Follow-up (2 entries)
- Days to follow up: 254 days; Days to first event: 254 days; First event: Event.
- Days to follow up: 440 days (1.2 years); Year of follow up: 2010.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASVRU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASVRU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 440
- Protocol: ANBL00B1, ANBL0532
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- ICDO Description: Retroperitoneum Periadrenal tissue Perinephric tissue Peripancreatic tissue Perirenal tissue Retrocecal tissue Retroperitoneal tissue
- Percent Tumor v/s Stroma: 80/20
